CCDI case PBCAMV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/07202f09-5d0c-406a-bd09-1c44e803250f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.8 years (3,954 days).

Biospecimens (3 samples)
- Sample 0DMWTN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMWTU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DMWTZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
